Somatic mutation profile of tumor specimen TCGA-DU-6404-02A (aliquot TCGA-DU-6404-02A-21D-A36O-08) from TCGA case TCGA-DU-6404, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 24.7 years (9,021 days).
Specimen TCGA-DU-6404-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcfa406d-c8dd-45bf-b4a2-87adc8cfbce5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6404-10A (Blood Derived Normal), aliquot TCGA-DU-6404-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95c1a0c7-df86-41c5-adbe-57df4fa10ad3

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, In Frame Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD1 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767055661, COSV53271278; called by muse, mutect2, varscan2
- CNTNAP5 | c.2810G>C p.G937A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV70482924; called by muse, mutect2, varscan2
- CREBBP | c.4231G>C p.G1411R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52118491, COSV52144101; called by muse, mutect2, varscan2
- FPR1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs145808420; called by muse, mutect2, varscan2
- IQSEC2 | c.1885C>T p.H629Y (on ENST00000642864 / NM_001111125.3; = p.H424Y on NM_015075.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV100944749; called by muse, mutect2, varscan2
- MACF1 | c.10442A>G p.E3481G | Missense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99245216; called by muse, mutect2, varscan2
- NR3C2 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.024); catalogued as rs754997003; called by muse, mutect2, varscan2
- PIK3R1 | c.1756C>G p.Q586E (on ENST00000521381 / NM_181523.3; = p.Q316E on NM_181504.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV57126219; called by muse, mutect2, varscan2
- RASGRP1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370888491; called by muse, mutect2, varscan2
- SPP1 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.411); catalogued as rs757338944, COSV52951625; called by muse, mutect2, varscan2
- ABL1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRINP3 | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- CEP350 | c.5132A>G p.E1711G | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CIITA | c.1691_1693del p.F564_E565delins* | Nonsense Mutation (DEL) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- CREB3L3 | c.1238A>C p.N413T | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2
- CSTF2T | c.88_90del p.E30del | In Frame Del (DEL) | VAF 46/152 reads (30%) | called by pindel, varscan2
- DEAF1 | c.1221_1224delinsT p.E408del | In Frame Del (DEL) | VAF 31/127 reads (24%) | called by pindel, varscan2*
- ETS2 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MRPL13 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- RPS27A | c.406T>C p.F136L | Missense Mutation (SNP) | VAF 5/121 reads (4%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.989); called by muse, mutect2
- SH3RF2 | c.1940A>G p.N647S | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SMG1 | c.4963A>G p.N1655D | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- TMCO3 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2
- TUT1 | c.389A>C p.E130A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- UNC13B | c.2947A>G p.K983E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ARHGEF1 | c.1272G>A p.L424= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.306C>T p.F102= | Silent (SNP) | VAF 21/436 reads (5%) | called by muse, mutect2
- CTSG | c.537C>T p.Y179= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1476151995, COSV53535132; called by muse, mutect2, varscan2
- HDLBP | c.1908C>T p.C636= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs187198864, COSV60497530; called by muse, mutect2, varscan2
- MBNL3 | c.43C>T p.L15= | Silent (SNP) | VAF 67/217 reads (31%) | called by muse, mutect2, varscan2
- PREPL | c.45T>C p.S15= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- PRKG1 | c.1230T>C p.R410= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- RAD21 | c.21T>C p.V7= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SF3B3 | c.432G>A p.L144= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as COSV56785280; called by muse, mutect2, varscan2
- SSU72P8 | c.552A>G p.G184= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
